Gene-level copy-number profile of tumor specimen C3L-08654-05 from CPTAC case C3L-08654, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 75.5 years (27,594 days).
Specimen C3L-08654-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 356d3b91-1877-4cf0-9620-fd3cfa3143b3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-08654-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,722 have no estimate.
https://portal.gdc.cancer.gov/files/a3bb1f97-07e8-42b5-a246-a8964b711f95

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 41; copy number 1: 875; copy number 2: 16,033; copy number 3: 22,818; copy number 4: 7,166; copy number 5: 8,803; copy number 6: 1,377; copy number 7: 1,235; copy number 8: 168; copy number 9: 87; copy number 10: 54; copy number 11: 32; copy number 12: 3; copy number 13: 15; copy number 14: 62; copy number 18: 30; copy number 22: 6; copy number 25: 13; copy number 31: 16; copy number 50: 34; copy number 83: 17; copy number 100: 16.

Homozygous deletions (total copy number 0; autosomes only): 41 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,724,512–1,745,992, 2 genes (within-gene range 0–2): AL031282.1, SLC35E2A.
- chr9:40,992,249–41,218,410, 1 gene (within-gene range 0–2): FRG1HP.
- chr9:41,100,793–42,499,134, 38 genes: BX255923.2, FOXD4L6, CBWD6, MIR4477A, RNA5SP530, AL845472.1, PTGER4P2-CDK2AP2P2, CDK2AP2P1, MYO5BP1, AL354718.2, CDRT15P6, AL354718.1, AL591926.3, SNORA70, RN7SL565P, AL591926.7, AL591926.6, AL591926.5, AL591926.2, FAM242F, Y_RNA, AL591926.1, AL591926.4, AL162731.1, CNTNAP3B, RBM17P3, CR788268.1, RN7SL343P, SPATA31A6, AL445584.1, FAM74A7, AL445584.3, AL445584.2, FKBP4P6, SDR42E1P2, ATP5F1AP1, RAB28P3, RBPJP6.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,788 genes in 29 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:32,457,835–32,901,438, 15 genes, copy number 8: RN7SL122P, AL033529.1, ZBTB8B, ZBTB8A, ZBTB8OS, Y_RNA, RBBP4, SYNC, AC114489.1, KIAA1522, YARS1, S100PBP, FNDC5, HPCA, TMEM54.
- chr1:34,640,157–35,122,484, 18 genes, copy number 7: AC099565.1, MIR552, SMIM12, GJB5, GJB4, AL121988.1, GJB3, GJA4, AL122010.1, DLGAP3, AC114490.3, AC114490.1, AC114490.2, TMEM35B, ZMYM6, ZMYM1, RPL12P45, EFCAB14P1.
- chr1:36,415,827–37,709,719, 25 genes, copy number 7: OSCP1, SNORA63C, MRPS15, CSF3R, FTLP18, AC117945.1, GRIK3, AL353604.1, MIR4255, RNU6-636P, RNA5SP43, RPS29P6, LINC01137, ZC3H12A, MIR6732, MEAF6, MIR5581, SNIP1, FTH1P1, AL034379.1, DNALI1, GNL2, RSPO1, C1orf109, CDCA8.
- chr1:42,335,386–42,424,232, 3 genes, copy number 7 (within-gene range 6–7): AC096540.1, RIMKLA, AL513331.1.
- chr1:154,924,740–154,994,315, 11 genes, copy number 7: PMVK, AL451085.1, PBXIP1, Metazoa_SRP, PYGO2, AL451085.2, SHC1, CKS1B, MIR4258, FLAD1, LENEP.
- chr1:196,819,731–196,959,622, 4 genes, copy number 9 (within-gene range 5–9): CFHR1, BX248415.1, CFHR4, CFHR2.
- chr1:243,488,233–243,851,079, 1 gene, copy number 7 (within-gene range 5–7): AKT3.
- chr1:243,624,666–248,937,043, 168 genes, copy number 7 (broad region; genes not listed).
- chr2:96,875,882–98,618,515, 50 genes, copy number 8: FAM178B, AC092636.1, Metazoa_SRP, RNA5SP101, AC079395.3, AC079395.2, AC079395.1, TRIM43CP, AC018892.1, AC018892.2, IGKV2OR2-1, IGKV2OR2-2, IGKV1OR2-3, GPAT2P2, FAHD2B, AC018892.3, RN7SL313P, ANKRD36, AC159540.2, AC159540.1, IGKV1OR2-9, IGKV2OR2-10, IGKV2OR2-7D, IGKV3OR2-5, IGKV1OR2-6, IGKV2OR2-7, IGKV2OR2-8, IGKV1OR2-11, AC092683.1, AC092683.2, ANKRD36B, AC017099.1, AC017099.2, UBTFL6, COX5B, ACTR1B, C2orf92, RNU4-8P, ZAP70, TMEM131, HMGN1P36, RNU7-96P, VWA3B, ATP5F1BP1, AC092675.1, CNGA3, AC092675.2, INPP4A, COA5, UNC50.
- chr2:106,801,600–107,365,873, 7 genes, copy number 8 (within-gene range 6–8): ST6GAL2, ST6GAL2-IT1, AC016994.1, AC005040.2, PPP1R2P5, AC005040.1, LINC01789.
- chr2:111,006,015–111,523,376, 1 gene, copy number 11 (within-gene range 6–11): MIR4435-2HG.
- chr2:111,119,378–114,420,302, 99 genes, copy number 9–14 (broad region; genes not listed).
- chr3:70,751,123–72,583,535, 29 genes, copy number 8–11: COX6CP6, HMGB1P36, RNU6-281P, FOXP1, AC097634.4, FOXP1-AS1, MIR1284, AC097634.2, FOXP1-IT1, AC097634.3, AC097634.1, EIF4E3, GPR27, PROK2, RN7SL271P, LINC00877, UBE2Q2P9, AC105265.2, AC105265.3, AC105265.1, CCDC137P, LINC00870, AC112219.2, AC112219.1, AC134508.1, RYBP, AC104435.2, RNU1-62P, AC104435.1.
- chr6:43,705,949–43,852,333, 6 genes, copy number 8: AL136131.1, AL136131.2, VEGFA, AL136131.3, LINC02537, AL157371.1.
- chr6:46,997,708–47,042,350, 1 gene, copy number 7: ADGRF1.
- chr7:7,102,573–25,756,256, 231 genes, copy number 7 (broad region; genes not listed).
- chr8:41,577,187–43,674,591, 67 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr8:127,072,694–127,742,951, 10 genes, copy number 7: CASC19, PRNCR1, AC020688.1, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, CASC11, MYC.
- chr8:144,262,045–144,699,185, 40 genes, copy number 7: BOP1, MIR7112, SCX, HSF1, DGAT1, AC233992.1, MIR6848, SCRT1, SLC52A2, TMEM249, AC233992.2, FBXL6, ADCK5, CPSF1, MIR939, MIR1234, MIR6849, AC233992.3, SLC39A4, VPS28, TONSL, MIR6893, TONSL-AS1, CYHR1, AC084125.1, KIFC2, FOXH1, PPP1R16A, AC084125.2, GPT, MFSD3, RECQL4, AC084125.4, LRRC14, LRRC24, C8orf82, ARHGAP39, AC084125.3, Metazoa_SRP, AF186192.1.
- chr17:30,477,362–31,382,116, 52 genes, copy number 7: GOSR1, ALOX12P1, AC011840.3, AC011840.5, TBC1D29P, AC011840.4, AC011840.2, KRT17P3, AC011840.1, AC005562.1, SMURF2P1, AC005562.2, SH3GL1P2, LRRC37BP1, RN7SL316P, SUZ12P1, AC127024.7, AC127024.3, AC127024.2, AC127024.8, CRLF3, AC127024.4, AC127024.5, AC127024.6, AC127024.1, ATAD5, AC130324.2, RNU6-298P, AC130324.1, TEFM, AC130324.3, ADAP2, AC138207.1, RN7SL138P, AC138207.5, AC138207.9, RNF135, AC138207.4, DPRXP4, AC138207.7, AC138207.3, AC138207.8, AC138207.6, AC138207.2, MIR4733, NF1, AC079915.1, OMG, EVI2B, AC134669.1, EVI2A, AK4P1.
- chr17:36,253,456–39,747,291, 128 genes, copy number 7–100 (within-gene range 3–100) (broad region; genes not listed).
- chr18:3,066,807–3,406,818, 12 genes, copy number 9: MYOM1, RNU7-25P, AP005329.2, AP005329.3, MYL12A, AP005329.1, MYL12B, AP001025.1, LINC01895, RPL31P59, IGLJCOR18, RPL21P127.
- chr19:27,638,483–31,787,255, 75 genes, copy number 10–22 (broad region; genes not listed).
- chr19:32,581,190–32,676,597, 5 genes, copy number 14 (within-gene range 5–14): PDCD5, ANKRD27, SNORA68B, RPS12P31, RN7SL789P.
- chr19:32,875,925–33,773,509, 26 genes, copy number 7–8: CEP89, RPL31P60, FAAP24, RHPN2, AC008521.1, AC008521.2, GPATCH1, WDR88, LRP3, AC008738.1, AC008738.7, SLC7A10, AC008738.4, AC008738.6, AC008738.3, CEBPA, AC008738.5, CEBPA-DT, AC008738.2, RPS3AP50, AKR1B1P7, CEBPG, PEPD, AC010485.1, RPL21P131, CHST8.
- chr19:34,172,504–35,285,143, 61 genes, copy number 7–8 (broad region; genes not listed).
- chr19:37,907,208–39,786,291, 104 genes, copy number 8–10 (broad region; genes not listed).
- chr20:5,507,875–13,996,443, 108 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr20:45,890,144–64,327,972, 431 genes, copy number 7–9 (within-gene range 6–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 459. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
